Gene-level copy-number profile of tumor specimen TCGA-OR-A5JM-01A from TCGA case TCGA-OR-A5JM, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 25.6 years (9,359 days).
Specimen TCGA-OR-A5JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.31c0a89c-deca-4a99-8c8d-ff0a4152cc40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JM-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b8a96be-35c0-4c55-9610-7389931c11e9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 433; copy number 2: 13,308; copy number 3: 30,770; copy number 4: 13,154; copy number 5: 1,498; copy number 6: 51; copy number 7: 50; copy number 8: 58; copy number 9: 31; copy number 11: 62; copy number 12: 246; copy number 13: 3; copy number 14: 56; copy number 15: 80; copy number 16: 3; copy number 17: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JM-01A-11D-A29H-01): tumor purity 0.97, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 598 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:46,911,396–47,002,488, 1 gene, copy number 7: PTPN20.
- chr10:61,406,642–62,096,944, 7 genes, copy number 7 (within-gene range 3–7): TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr12:50,923,472–51,997,078, 37 genes, copy number 12–13: METTL7A, AC008121.2, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P.
- chr12:54,549,601–55,132,750, 14 genes, copy number 11 (within-gene range 3–11): PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2.
- chr12:57,253,762–59,812,576, 72 genes, copy number 12–17 (within-gene range 4–17) (broad region; genes not listed).
- chr12:61,600,067–63,055,765, 29 genes, copy number 14: DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5.
- chr12:63,623,788–63,795,718, 1 gene, copy number 15 (within-gene range 4–15): AC084357.2.
- chr12:63,682,523–73,208,317, 196 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).
- chr12:74,656,561–77,163,638, 50 genes, copy number 8 (within-gene range 5–8): AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1.
- chr12:80,792,520–81,261,210, 7 genes, copy number 8 (within-gene range 5–8): LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699.
- chr12:81,270,669–81,312,422, 1 gene, copy number 8: PPFIA2-AS1.
- chr12:84,448,625–84,939,668, 4 genes, copy number 13–16: AC087888.1, AC093027.1, SLC6A15, AC128657.1.
- chr12:86,599,578–88,430,550, 18 genes, copy number 11: AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA.
- chr12:107,093,298–109,573,580, 58 genes, copy number 12: AC078929.1, AC007649.1, SETP7, BTBD11, AC009774.1, RNA5SP371, AC007540.1, Y_RNA, PWP1, AC007622.1, PRDM4, AC007622.2, ASCL4, AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1, WSCD2, AC009729.1, CMKLR1, LINC01498, FICD, SART3, AC008119.1, ISCU, TMEM119, SELPLG, AC007569.1, MIR4496, CORO1C, RNU7-169P, Y_RNA, AC087893.1, SSH1, AC087893.3, AC087893.2, MIR619, DAO, SVOP, RNU6-361P, AC190387.1, USP30, USP30-AS1, RNA5SP372, ALKBH2, UNG, AC007637.1, ACACB, FOXN4, MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P.
- chr12:112,570,380–113,480,624, 27 genes, copy number 14 (within-gene range 11–14): RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1.
- chr12:114,077,133–115,364,745, 25 genes, copy number 9: AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459, TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2.
- chr12:117,453,012–118,145,584, 9 genes, copy number 12 (within-gene range 3–12): KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1.
- chr18:20,946,906–22,647,688, 42 genes, copy number 7: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.

Autosomal genes at a single copy (total copy number 1): 433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
